Somatic mutation profile of tumor specimen TCGA-DD-A4NL-01A (aliquot TCGA-DD-A4NL-01A-11D-A28X-10) from TCGA case TCGA-DD-A4NL, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 46.2 years (16,874 days).
Specimen TCGA-DD-A4NL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f268a13-9725-4a50-b72c-3ff955799715.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NL-11A (Solid Tissue Normal), aliquot TCGA-DD-A4NL-11A-11D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35e2d90b-92a7-43ed-ae10-16da5dd696c9

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 20, Silent 7, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1004A>T p.K335I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62688046, COSV62689047, COSV62695316; called by muse, mutect2, varscan2
- ADAM21 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV50790179; called by muse, mutect2, varscan2
- AMY2B | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 114/313 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1015120800, COSV63714754, COSV63717338; called by muse, varscan2
- IL1R1 | c.1386C>G p.S462R | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV52105481; called by muse, mutect2, varscan2
- IL6ST | c.565_576del p.V189_V192del | In Frame Del (DEL) | VAF 27/123 reads (22%) | catalogued as COSV61139702; called by mutect2, pindel, varscan2
- KIF1A | c.2504C>A p.T835N | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV57485820; called by muse, mutect2
- KLRK1 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.421); catalogued as rs774615042, COSV53698235; called by muse, mutect2, varscan2
- MMS22L | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV51519125; called by muse, mutect2, varscan2
- PDZD2 | c.3212G>T p.G1071V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV56854562, COSV99226249; called by muse, mutect2, varscan2
- RASSF10 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61754390; called by muse, mutect2, varscan2
- RTL6 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV57979431; called by muse, mutect2, varscan2
- SCAMP3 | c.925G>C p.A309P | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV56944332; called by muse, mutect2, varscan2
- SLC13A3 | c.371C>G p.P124R | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51713539; called by muse, varscan2
- SLC30A4 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56005490; called by muse, mutect2, varscan2
- TAS2R20 | c.398T>C p.V133A | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV67854138; called by muse, mutect2
- TMEM63A | c.1238T>C p.I413T | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV64762766; called by muse, mutect2, varscan2
- TUBA8 | c.173A>T p.N58I | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV57812671; called by muse, mutect2, varscan2
- YEATS4 | c.22T>C p.F8L | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV56088480; called by muse, mutect2, varscan2
- ZNF280B | c.227A>T p.D76V | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV64528441, COSV64528608; called by muse, mutect2
- ZNF362 | c.491T>A p.I164N | Missense Mutation (SNP) | VAF 19/323 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV65031270; called by muse, mutect2
- ZNF462 | c.1470G>T p.Q490H | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs758352488, COSV52934178; called by muse, mutect2, varscan2
- DHX16 | c.2073T>C p.D691= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV53313153; called by muse, mutect2, varscan2
- EPHB4 | c.2733T>A p.S911= | Silent (SNP) | VAF 14/189 reads (7%) | catalogued as COSV62268387; called by muse, mutect2
- JAKMIP1 | c.969A>G p.R323= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV51525941; called by muse, mutect2
- KCTD8 | c.1299G>A p.K433= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV63587209; called by muse, mutect2
- PRDM12 | c.720G>T p.A240= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV99446421; called by muse, mutect2
- SSH1 | c.1233A>G p.E411= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as rs1459105213, COSV100425876; called by muse, mutect2
- UNC13C | c.6195A>G p.V2065= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV52856008; called by muse, mutect2, varscan2
